TCGA case TCGA-YU-A90R — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/82fd0cb2-cf2b-4ca1-8498-204118fbaf50

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 47 years; Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 47.8 years (17,471 days); Year of diagnosis: 2009; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IB; AJCC pathologic T: T2; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,994 days (5.5 years); Ajcc serum tumor markers: S0; Sites of involvement: Tunica Vaginalis.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,766 days (4.8 years); Disease response: Tumor Free.
- Days to follow up: 1,994 days (5.5 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27: Lactate Dehydrogenase 915; Alpha Fetoprotein 14.1; Human Chorionic Gonadotropin 4.16.
- Day 125: Lactate Dehydrogenase 357; Alpha Fetoprotein 3.17; Human Chorionic Gonadotropin 0.1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Natural Father; Relationship primary diagnosis: Gastric Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YU-A90R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-YU-A90R-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-YU-A90R-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YU-A90R-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
